Somatic mutation profile of tumor specimen TCGA-EY-A2ON-01A (aliquot TCGA-EY-A2ON-01A-21D-A18P-09) from TCGA case TCGA-EY-A2ON, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 61.9 years (22,624 days).
Specimen TCGA-EY-A2ON-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57ca233c-4b62-40d3-bbc1-d325b4c91281.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A2ON-10A (Blood Derived Normal), aliquot TCGA-EY-A2ON-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc769d27-4b60-4d66-a004-56400c24bb8a

The open-access MAF lists 76 somatic variants for this specimen: 61 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 14, Splice Region 2, Frame Shift Del 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 105/206 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as rs281875334, CM122512, COSV100079763; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.4465C>T p.R1489C | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs773525683, COSV100068826; called by muse, mutect2, varscan2
- ABI3BP | c.977G>C p.R326P | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV52536843, COSV99427604; called by muse, mutect2, varscan2
- ADAMTS12 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100711329; called by muse, mutect2, varscan2
- ANGPTL3 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 58/103 reads (56%) | catalogued as COSV52001395; called by muse, mutect2, varscan2
- ATG13 | c.887C>A p.T296K | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV100365866; called by muse, mutect2, varscan2
- BNIP5 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as rs371753547; called by muse, mutect2, varscan2
- BTN1A1 | c.499G>C p.V167L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55069574, COSV99764465; called by muse, mutect2, varscan2
- CACNA1F | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100545082; called by muse, mutect2, varscan2
- CASD1 | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51971870, COSV99802796; called by muse, mutect2, varscan2
- CCDC39 | c.389A>C p.D130A | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99869827; called by muse, mutect2, varscan2
- CHD4 | c.3383T>G p.V1128G (on ENST00000357008 / NM_001363606.2; = p.V1141G on NM_001273.5) | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100538439; called by muse, mutect2, varscan2
- CLTCL1 | c.4910A>G p.D1637G (on ENST00000427926 / NM_007098.4; = p.D1580G on NM_001835.4) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.977); catalogued as COSV99311022; called by muse, mutect2, varscan2
- COL11A1 | c.162A>G p.I54M | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV62191062; called by muse, mutect2, varscan2
- DENND4C | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100991449; called by muse, mutect2, varscan2
- DNAJC7 | c.301C>G p.R101G | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100347963, COSV57269221; called by muse, mutect2, varscan2
- DOK1 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs942203972, COSV99284127; called by muse, mutect2, varscan2
- ECD | c.1572T>A p.F524L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100881461; called by muse, mutect2, varscan2
- ELF1 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99523183; called by muse, mutect2, varscan2
- EYA4 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100766053; called by muse, mutect2
- FGD5 | c.3391C>T p.R1131W | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749539714, COSV53247721; called by muse, mutect2, varscan2
- FLT4 | c.1723C>A p.L575I | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs773839174, COSV99987786; called by muse, mutect2, varscan2
- FOXR2 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100189548; called by muse, mutect2, varscan2
- FSTL1 | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV55236359, COSV99820822; called by muse, mutect2
- GLG1 | c.3041C>G p.S1014C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99216039; called by muse, mutect2, varscan2
- GPR55 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as rs773230056, COSV101235899, COSV67408740; called by muse, mutect2, varscan2
- GPRC5C | c.844C>T p.R282C (on ENST00000652232; = p.R237C on NM_018653.4) | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs374321302; called by muse, mutect2, varscan2
- GTF3C2 | c.1271A>G p.N424S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs776740063, COSV99273003; called by muse, mutect2, varscan2
- ITGA3 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99143849; called by muse, mutect2, varscan2
- KCNG4 | c.1411C>A p.L471I | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as COSV100377109; called by muse, mutect2, varscan2
- KCNQ2 | c.1895C>T p.S632F (on ENST00000359125 / NM_172107.4; = p.S604F on NM_004518.6) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100610376; called by muse, mutect2, varscan2
- KCTD13 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774531778, COSV100442022; called by muse, mutect2, varscan2
- LGALS8 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV99436599; called by muse, mutect2, varscan2
- LRRC2 | c.931T>G p.F311V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99947534; called by muse, mutect2, varscan2
- LRRC29 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1169340894, COSV100440897; called by muse, mutect2, varscan2
- MAGI1 | c.1592C>T p.T531I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100441884, COSV58343744; called by muse, mutect2, varscan2
- MAP3K7CL | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.972); catalogued as rs764189661, COSV99726744; called by muse, mutect2, varscan2
- MROH9 | c.1026C>T p.D342= | Splice Region (SNP) | VAF 10/50 reads (20%) | catalogued as rs776956950, COSV63012605; called by muse, mutect2, varscan2
- MSL2 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs747396367, COSV99387655; called by muse, mutect2, varscan2
- MYO1D | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780113381, COSV100554589, COSV59022936; called by muse, mutect2, varscan2
- MYOM2 | c.2545G>A p.V849M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768644682, COSV100037871; called by muse, mutect2, varscan2
- NUP62 | c.68C>G p.T23R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV100352186; called by muse, mutect2, varscan2
- OR1S1 | c.511A>T p.T171S | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.885); catalogued as COSV100515441; called by muse, mutect2, varscan2
- PIK3CA | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV55995757, COSV99081707; called by muse, mutect2, varscan2
- PPP2CA | c.794A>T p.Y265F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99196045; called by muse, mutect2, varscan2
- REEP2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs145269051; called by muse, mutect2, varscan2
- REG3A | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100532806; called by muse, mutect2
- RIC1 | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 22/329 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99317591; called by muse, mutect2
- RTKN | c.383T>A p.I128N (on ENST00000272430 / NM_001015055.2; = p.I115N on NM_033046.2) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99269759; called by muse, mutect2
- SETBP1 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.843); catalogued as COSV99953967; called by muse, mutect2, varscan2
- SMAP2 | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761250331, COSV101019134; called by muse, mutect2, varscan2
- SNRNP200 | c.2582A>T p.Y861F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV100107814; called by muse, mutect2, varscan2
- STKLD1 | c.224T>C p.M75T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100912110; called by muse, mutect2, varscan2
- STUB1 | c.580C>G p.R194G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99555856; called by muse, mutect2, varscan2
- SUN2 | c.426C>A p.G142= | Splice Region (SNP) | VAF 3/37 reads (8%) | catalogued as COSV53307713; called by muse, mutect2
- TMEM52 | c.572T>G p.V191G | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100205607; called by muse, mutect2
- UBFD1 | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99563352; called by muse, mutect2, varscan2
- USH2A | c.2348A>T p.N783I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56327866, COSV56347503; called by muse, mutect2, varscan2
- WDFY3 | c.699G>C p.K233N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV99884396; called by muse, mutect2, varscan2
- SDF2L1 | c.270del p.C92Afs*13 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- TP53 | c.579_585del p.L194Efs*51 | Frame Shift Del (DEL) | VAF 44/53 reads (83%) | called by mutect2, pindel, varscan2
- AUTS2 | c.2454C>T p.S818= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs777405806, COSV61382660; called by muse, mutect2, varscan2
- BAIAP3 | c.3435G>A p.L1145= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99136298; called by muse, mutect2, varscan2
- FAM47B | c.168C>T p.D56= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs776418751, COSV100264452; called by muse, mutect2, varscan2
- GPX8 | c.126T>A p.P42= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99697148; called by muse, mutect2
- LRRC7 | c.609C>A p.I203= (on ENST00000651989 / NM_001370785.2; = p.I170= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as rs764781045, COSV99228081; called by muse, mutect2, varscan2
- NOS1AP | c.609T>A p.T203= | Silent (SNP) | VAF 63/177 reads (36%) | catalogued as COSV100723115; called by muse, mutect2, varscan2
- PCDHB9 | c.2124C>T p.F708= | Silent (SNP) | VAF 86/387 reads (22%) | catalogued as rs1179429492; called by muse, mutect2, varscan2
- PHRF1 | c.3924G>A p.A1308= (on ENST00000264555 / NM_001286581.2; = p.A1307= on NM_020901.4) | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs375739393; called by muse, mutect2, varscan2
- PLSCR2 | c.471T>C p.G157= (on ENST00000497985 / NM_001199978.1; = p.G84= on NM_020359.2) | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100367789; called by muse, mutect2
- POM121 | c.876C>T p.I292= (on ENST00000434423; = p.I27= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as COSV99988705; called by muse, mutect2, varscan2
- PRKDC | c.2754G>A p.A918= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs748858597, COSV100041477; called by muse, mutect2, varscan2
- SMG5 | c.1743C>T p.F581= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100700848; called by muse, mutect2, varscan2
- TECTA | c.5142C>T p.Y1714= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs151087951, COSV50705029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNK4 | c.1824G>T p.V608= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99890812; called by muse, mutect2, varscan2
- MIR1185-2 | n.72C>A | RNA (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
